TCGA case TCGA-2G-AAFG — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: Erasmus MC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/630c683d-d1a2-4bec-aa20-38ef59227d97

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 30 years; Year of birth: 1968; Vital status: Alive.

Diagnoses (3)
1. Seminoma, NOS (the primary disease): ICD-O-3 morphology code: 9061/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 30.1 years (11,002 days); Year of diagnosis: 1998; Method of diagnosis: Orchiectomy; AJCC staging edition: 5th; AJCC clinical T: T1; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IS; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 6,183 days (16.9 years); Ajcc serum tumor markers: S1; Sites of involvement: Rete Testis.
   Pathology details: Intratubular germ cell neoplasia present: No; Lymphatic invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 49 days; Days to treatment end: 65 days; Treatment dose: 26 Gy; Treatment outcome: Complete Response; Number of fractions: 13; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bleomycin + Cisplatin + Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 2,506 days (6.9 years); Days to treatment end: 2,565 days (7.0 years); Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
2. Subsequent primary of the testis (histology not recorded by GDC). Age at diagnosis: 37.0 years (13,497 days); Days to diagnosis: 2,495 days (6.8 years); Prior treatment: Yes.
3. Subsequent primary of the skin (histology not recorded by GDC). Age at diagnosis: 46.1 years (16,829 days); Days to diagnosis: 5,827 days (16.0 years); Prior treatment: Yes.

Follow-up (4 entries)
- Days to follow up: 5,601 days (15.3 years); Disease response: Tumor Free.
- Days to follow up: 5,819 days (15.9 years); Disease response: Tumor Free.
- Days to follow up: 6,183 days (16.9 years); Disease response: Tumor Free.
- Karnofsky performance status: 90; ECOG performance status: 0; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -3: Lactate Dehydrogenase 467; Alpha Fetoprotein 2.5.
- Day 49: Lactate Dehydrogenase 219; Alpha Fetoprotein 3.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Conceived 1 or more children by natural conception; Undescended testis history: No.

Family history
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Lymphoma.
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Ovarian Cancer.
- Relative with cancer history: yes; Relationship type: Cousin; Relationship primary diagnosis: Testicular Cancer.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AAFG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 350 mg.
  Slide TCGA-2G-AAFG-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-2G-AAFG-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAFG-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary; Preservation method: OCT; Initial weight: 170 mg.
  Slide TCGA-2G-AAFG-05A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-2G-AAFG-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; History hypospadias: No; History fertility: Fathered > or = 1 child by natural conception; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Postoperative treatment list: Postoperative treatment: Radiation.
- Stage record: AJCC pathologic tumor stage: IS.
- Primary pathology: Submitted tumor site: Testes; Testis tumor macroextent: Involves testis only; Testis tumor microextent: Rete Testis; Intratubular germ cell neoplasm: Absent; Lymphovascular invasion: No; Post orchi lymph node dissection: No; First treatment success: No Measureable Tumor or Tumor Markers.
- Primary pathology, Histology list, Histology: Histologic diagnosis: Seminoma, NOS.
- Primary pathology, Pre orchi serum marker info: Pre orchi LDH: 467; Pre orchi afp: 2.5.
- Primary pathology, Post orchi serum marker info: Post orchi LDH: 219; Post orchi afp: 3.
- Primary pathology, Molecular test result list: Molecular test result: Lactate Dehydrogenase (LDH) - Normal; Molecular test result: Human Chorionic Gonadotropin (HCG) - Normal; Molecular test result: Alpha Fetaprotein (AFP) - Normal.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site: Testes.
- Follow-up form 1: Lost to follow-up: No; Post orchi lymph node dissection: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes.
- Follow-up form 1, New tumor event 2: New tumor event type: New Primary Tumor; New tumor event site other: skin (melanoma).
- Follow-up form 2: Lost to follow-up: No; Post orchi lymph node dissection: No; Tumor status: Tumor free; Treatment outcome first course: No Measureable Tumor or Tumor Markers; New tumor event diagnosis indicator: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 6,183 days; disease-specific survival: no event (censored), 6,183 days; disease-free interval: event (new tumor event after initially disease-free), 2,495 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,495 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2G-AAFG-01A-11D-A42X-01): tumor purity 0.45, ploidy 2.94, whole-genome doublings 1.
Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2G-AAFG-05A-11D-A42X-01): tumor purity 0.26, ploidy 2.97, whole-genome doublings 1.
